Somatic mutation profile of tumor specimen BA3194D (aliquot aq-BA3194D) from BEATAML1.0 case 2757, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow.
Specimen BA3194D: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8161d1a-536a-464f-9ec7-63ad309bd4ed.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3337D (Solid Tissue Normal), aliquot aq-BA3337D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/820950dd-1ac0-4607-9422-10fc2d823827

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.430dup p.E144Gfs*26 | Frame Shift Ins (INS) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- NFE2 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 54/232 reads (23%) | called by muse, mutect2, varscan2
